CCDI case PBCDJY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b3fafc5f-4a9f-4321-9984-ba6e552c599d

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 17.2 years (6,285 days).

Biospecimens (3 samples)
- Sample 0DPE95: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPE9E: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPE9L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
